Somatic mutation profile of tumor specimen C3L-09227-03 (aliquot CPT0492910006) from CPTAC case C3L-09227, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 77.0 years (28,131 days).
Specimen C3L-09227-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e338441-fbb9-441e-9449-9aee63058edc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09227-31 (Blood Derived Normal), aliquot CPT0497130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/070714cf-7f56-4f50-a471-74fbe73a57ab

The open-access MAF lists 369 somatic variants for this specimen: 289 protein-altering or splice-affecting, 70 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 70, Nonsense Mutation 38, Intron 7, Splice Site 7, Frame Shift Del 4, RNA 2, Splice Region 2, In Frame Del 2, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 63/117 reads (54%) | catalogued as rs879254083, CM122159, COSV53787015; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 153/302 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61684417, COSV61684645, COSV61684738; called by muse, mutect2, varscan2
- ABCA12 | c.6376G>T p.E2126* (on ENST00000272895 / NM_173076.3; = p.E1808* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 84/185 reads (45%) | catalogued as COSV55950272; called by muse, mutect2, varscan2
- ABCB4 | c.2092C>A p.L698M | Missense Mutation (SNP) | VAF 159/437 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.133); catalogued as COSV55942749; called by muse, mutect2, varscan2
- AHNAK | c.10129G>T p.D3377Y | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57235409; called by muse, mutect2, varscan2
- AKAP9 | c.6430G>T p.E2144* (on ENST00000359028; = p.E2112* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/196 reads (29%) | catalogued as COSV62355365; called by muse, mutect2, varscan2
- AMPH | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 112/366 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs769186615; called by muse, mutect2, varscan2
- ANKIB1 | c.2788G>T p.D930Y | Missense Mutation (SNP) | VAF 126/475 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.254); catalogued as COSV99729092; called by muse, mutect2, varscan2
- ARHGAP28 | c.1900C>T p.R634* (on ENST00000383472 / NM_001366230.1; = p.R475* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 114/224 reads (51%) | catalogued as rs773098375, COSV51644954; called by muse, mutect2, varscan2
- ARID1A | c.5356G>T p.E1786* | Nonsense Mutation (SNP) | VAF 173/335 reads (52%) | catalogued as COSV61375349, COSV61393393; called by muse, mutect2, varscan2
- BEST1 | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 156/311 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.164); catalogued as COSV56446076; called by muse, mutect2, varscan2
- BRINP3 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 132/306 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100818001; called by muse, mutect2, varscan2
- C1orf105 | c.162G>T p.L54F | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV51131515; called by muse, mutect2, varscan2
- C4orf54 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 216/450 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.773); catalogued as rs746236838; called by muse, mutect2, varscan2
- CDK8 | c.277G>C p.V93L | Missense Mutation (SNP) | VAF 23/320 reads (7%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.94); catalogued as COSV67419388, COSV67419755, COSV67422527; called by muse, mutect2
- CHAT | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 98/188 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60332949; called by muse, mutect2, varscan2
- CNOT10 | c.462G>T p.L154F | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs370558352; called by mutect2, varscan2
- COL17A1 | c.1889del p.G630Dfs*53 | Frame Shift Del (DEL) | VAF 58/417 reads (14%) | catalogued as COSV100793343; called by mutect2, pindel, varscan2
- DHX35 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 117/394 reads (30%) | catalogued as rs1230844230; called by muse, mutect2, varscan2
- EHD3 | c.59C>A p.T20K | Missense Mutation (SNP) | VAF 142/296 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.666); catalogued as COSV59030085; called by muse, mutect2, varscan2
- EP300 | c.3530G>T p.C1177F | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54326828; called by muse, mutect2
- F12 | c.797G>T p.C266F | Missense Mutation (SNP) | VAF 212/434 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1015683478, COSV53693357; called by muse, mutect2, varscan2
- FBXL13 | c.673C>A p.R225S | Missense Mutation (SNP) | VAF 119/233 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.423); catalogued as COSV57545472; called by muse, mutect2, varscan2
- FIGN | c.1916C>A p.S639Y | Missense Mutation (SNP) | VAF 169/342 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100293101; called by muse, mutect2, varscan2
- FLG | c.4666C>A p.H1556N | Missense Mutation (SNP) | VAF 140/316 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV64238442; called by muse, mutect2, varscan2
- GABRA5 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 173/340 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs764850266, COSV100165668, COSV59483862; called by muse, mutect2, varscan2
- GJB3 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 121/365 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as rs1006731339; called by muse, mutect2, varscan2
- GRAMD1C | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as rs76878239; called by muse, mutect2, varscan2
- HAGHL | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 188/370 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs771161789; called by mutect2, varscan2
- HBS1L | c.1058C>A p.P353Q | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100892528; called by muse, mutect2, varscan2
- HSPA5 | c.395T>C p.I132T | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); catalogued as rs191087735, COSV61029886; called by muse, mutect2, varscan2
- IGF2 | c.474G>T p.P158= (on ENST00000434045 / NM_001127598.3; = p.P102= on NM_000612.6) | Splice Region (SNP) | VAF 128/257 reads (50%) | catalogued as COSV104394934, COSV56099157; called by muse, mutect2, varscan2
- IL7R | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 110/239 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV57407044, COSV57407423; called by muse, mutect2, varscan2
- KIF15 | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 94/208 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs749109521; called by muse, mutect2, varscan2
- KIF21B | c.3214C>A p.Q1072K | Missense Mutation (SNP) | VAF 187/414 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV100145402; called by muse, mutect2, varscan2
- KMT2C | c.2345C>A p.S782Y | Missense Mutation (SNP) | VAF 36/608 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV100078277; called by muse, mutect2
- LFNG | c.822-1G>T p.X274_splice (on ENST00000222725 / NM_001040167.2; = p.X145_splice on NM_002304.2) | Splice Site (SNP) | VAF 131/433 reads (30%) | catalogued as COSV99761671; called by muse, mutect2, varscan2
- LRBA | c.4364G>T p.C1455F | Missense Mutation (SNP) | VAF 85/159 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63951149; called by muse, mutect2, varscan2
- LRP1B | c.11564C>A p.S3855Y | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV67259266; called by muse, mutect2, varscan2
- LZTS1 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 187/385 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs771940536; called by muse, mutect2, varscan2
- MAP3K19 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.162); catalogued as rs760386140; called by muse, mutect2, varscan2
- MECOM | c.1679G>T p.R560L (on ENST00000468789 / NM_001105078.4; = p.R748L on NM_004991.4) | Missense Mutation (SNP) | VAF 180/375 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.402); catalogued as COSV52958497; called by muse, mutect2, varscan2
- METTL2A | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61045187; called by muse, mutect2
- MRAS | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 199/426 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56673172; called by muse, mutect2, varscan2
- MUC17 | c.8047C>A p.P2683T | Missense Mutation (SNP) | VAF 105/363 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.908); catalogued as rs1428227196; called by muse, mutect2, varscan2
- MYO7B | c.5386G>T p.V1796F | Missense Mutation (SNP) | VAF 226/484 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs200072136, COSV101268389; called by muse, mutect2, varscan2
- NEU4 | c.859G>A p.A287T (on ENST00000391969 / NM_001167602.3; = p.A299T on NM_080741.4) | Missense Mutation (SNP) | VAF 349/686 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs371852061, COSV100371842; called by muse, mutect2, varscan2
- NFE2L2 | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 116/265 reads (44%) | catalogued as COSV101229384; called by muse, mutect2, varscan2
- OR10A7 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 172/323 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs773592123; called by muse, mutect2, varscan2
- OR2AJ1 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 166/342 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs756137973; called by muse, mutect2, varscan2
- OR4Q3 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 131/410 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100057413; called by muse, mutect2, varscan2
- OR5W2 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV60618484; called by muse, mutect2, varscan2
- OTOG | c.2873G>T p.G958V | Missense Mutation (SNP) | VAF 105/201 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1455245694; called by muse, mutect2, varscan2
- PBRM1 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 166/325 reads (51%) | catalogued as COSV56275393; called by muse, mutect2, varscan2
- PDXDC1 | c.1572-1G>T p.X524_splice | Splice Site (SNP) | VAF 101/199 reads (51%) | catalogued as COSV55075709; called by muse, mutect2, varscan2
- PHOX2A | c.448C>A p.R150S | Missense Mutation (SNP) | VAF 276/538 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1350964049; called by muse, mutect2, varscan2
- PPP1R12A | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 132/279 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV99700445; called by muse, mutect2, varscan2
- PRSS16 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 148/327 reads (45%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.91); catalogued as COSV57916112; called by muse, mutect2, varscan2
- RANBP2 | c.8973G>T p.M2991I | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as COSV51705640; called by muse, mutect2, varscan2
- RBM15 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 222/428 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV63924224; called by muse, mutect2, varscan2
- RGSL1 | c.2495-1G>T p.X832_splice | Splice Site (SNP) | VAF 90/177 reads (51%) | catalogued as COSV54254168; called by muse, mutect2, varscan2
- RRP12 | c.3631C>A p.Q1211K | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100212840; called by muse, mutect2, varscan2
- SCIN | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 287/789 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV51692282; called by muse, mutect2, varscan2
- SDK1 | c.3112C>G p.L1038V | Missense Mutation (SNP) | VAF 32/559 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs371319205; called by muse, mutect2
- SEPTIN7 | c.396C>A p.D132E | Missense Mutation (SNP) | VAF 83/308 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.16); catalogued as COSV63254402; called by muse, mutect2, varscan2
- SH3BP4 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 201/375 reads (54%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV60646135; called by muse, mutect2, varscan2
- SLC26A6 | c.351G>T p.L117F | Missense Mutation (SNP) | VAF 155/334 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50893222; called by muse, mutect2, varscan2
- SLC4A1 | c.988C>A p.Q330K | Missense Mutation (SNP) | VAF 225/488 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as CM961311; called by muse, mutect2, varscan2
- TGFBR2 | c.369G>T p.M123I | Missense Mutation (SNP) | VAF 127/262 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV99848332; called by mutect2, varscan2
- TLR10 | c.2110G>T p.E704* | Nonsense Mutation (SNP) | VAF 130/284 reads (46%) | catalogued as COSV58302414; called by muse, mutect2, varscan2
- TMF1 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.603); catalogued as rs1337225590; called by muse, mutect2, varscan2
- TP53 | c.566C>A p.A189D | Missense Mutation (SNP) | VAF 132/258 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); catalogued as CM031755, CM1414529, COSV52815388, COSV52840299, COSV53050047, COSV53757315; called by muse, mutect2, varscan2
- TRPA1 | c.1942G>T p.D648Y | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1260312897; called by muse, mutect2, varscan2
- TSC2 | c.2546-1G>T p.X849_splice | Splice Site (SNP) | VAF 50/251 reads (20%) | catalogued as CS091024; called by muse, mutect2, varscan2
- TTC5 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 199/389 reads (51%) | catalogued as COSV51870952; called by muse, mutect2, varscan2
- UBR2 | c.3893C>A p.S1298Y | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65751960; called by muse, mutect2, varscan2
- URGCP-MRPS24 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 214/608 reads (35%) | catalogued as COSV58181923; called by muse, mutect2, varscan2
- USP34 | c.8577G>T p.R2859S | Missense Mutation (SNP) | VAF 168/358 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV68401229; called by muse, mutect2, varscan2
- ZNF425 | c.194G>C p.R65T | Missense Mutation (SNP) | VAF 78/495 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV65201559; called by muse, mutect2, varscan2
- ZNF804B | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 68/236 reads (29%) | catalogued as COSV60825524; called by muse, mutect2, varscan2
- ZNF804B | c.2609G>T p.R870I | Missense Mutation (SNP) | VAF 119/429 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV60814934, COSV60857982; called by muse, mutect2, varscan2
- ZZEF1 | c.2659C>A p.Q887K | Missense Mutation (SNP) | VAF 140/274 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs1300405959; called by muse, mutect2, varscan2
- AADAC | c.521C>A p.A174E | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ABCC12 | c.3307C>A p.H1103N | Missense Mutation (SNP) | VAF 147/299 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- ABCG5 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 140/280 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ADAM33 | c.1697G>T p.C566F | Missense Mutation (SNP) | VAF 143/302 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS20 | c.1535C>A p.T512K | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADGRG2 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 27/230 reads (12%) | called by muse, mutect2, varscan2
- AKNAD1 | c.1323G>T p.L441F | Missense Mutation (SNP) | VAF 177/303 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ALDH9A1 | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 133/276 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AMPH | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 80/283 reads (28%) | called by muse, mutect2, varscan2
- ANK3 | c.5624C>A p.P1875Q | Missense Mutation (SNP) | VAF 186/390 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ANKRD35 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 136/407 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- ARHGEF26 | c.2340C>A p.S780R | Missense Mutation (SNP) | VAF 218/457 reads (48%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ARRDC5 | c.528G>T p.E176D (on ENST00000381781; = p.E162D on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/264 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ATP1A2 | c.2612C>A p.A871E | Missense Mutation (SNP) | VAF 176/338 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, varscan2
- ATP6V0A1 | c.2113C>A p.P705T | Missense Mutation (SNP) | VAF 150/313 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AXIN1 | c.2010_2031del p.E671Sfs*27 | Frame Shift Del (DEL) | VAF 147/556 reads (26%) | called by mutect2, pindel, varscan2
- BARHL1 | c.713C>A p.A238D | Missense Mutation (SNP) | VAF 175/355 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- C20orf203 | c.339C>A p.S113R | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by mutect2, varscan2
- C2orf81 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 247/511 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- C3AR1 | c.422C>G p.S141C | Missense Mutation (SNP) | VAF 76/448 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C6 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 113/204 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNG3 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 61/337 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CASS4 | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 79/274 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CCDC141 | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 144/286 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC154 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- CDCA2 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 131/268 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CDH1 | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH17 | c.1340C>A p.P447H | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP250 | c.3801G>T p.Q1267H | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CERCAM | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 303/599 reads (51%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CGGBP1 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 128/288 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CGNL1 | c.1192C>A p.Q398K | Missense Mutation (SNP) | VAF 188/398 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CHRM3 | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 149/308 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CNTN1 | c.2652C>A p.C884* | Nonsense Mutation (SNP) | VAF 28/261 reads (11%) | called by muse, mutect2, varscan2
- CNTRL | c.5561C>A p.A1854E | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL12A1 | c.1476C>A p.F492L | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COPS7B | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 108/217 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.187); called by muse, varscan2
- CRISPLD1 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 101/212 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYBG2 | c.848C>A p.A283E | Missense Mutation (SNP) | VAF 221/433 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CSK | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 47/424 reads (11%) | called by muse, mutect2, varscan2
- CTSV | c.892C>A p.L298I | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DACH1 | c.1945G>T p.E649* (on ENST00000619232 / NM_001366712.1; = p.E395* on NM_004392.6) | Nonsense Mutation (SNP) | VAF 37/273 reads (14%) | called by muse, mutect2, varscan2
- DDIAS | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 87/172 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- DHX35 | c.1594-1G>T p.X532_splice | Splice Site (SNP) | VAF 97/315 reads (31%) | called by muse, mutect2, varscan2
- DNAH10 | c.9487C>A p.L3163M (on ENST00000409039; = p.L3102M on NM_207437.3) | Missense Mutation (SNP) | VAF 104/385 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DNAH2 | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DNAI1 | c.958C>A p.L320M | Missense Mutation (SNP) | VAF 139/297 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- DNAJC1 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 77/176 reads (44%) | called by muse, mutect2, varscan2
- DNAJC4 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 146/282 reads (52%) | called by muse, mutect2, varscan2
- DOCK9 | c.3376C>A p.Q1126K (on ENST00000376460 / NM_001366676.2; = p.Q1127K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/301 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- DPYSL3 | c.1155C>A p.S385R | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ENTPD8 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 151/275 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- EPAS1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 81/184 reads (44%) | called by muse, mutect2, varscan2
- EPDR1 | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- EPHB3 | c.1394C>A p.S465* | Nonsense Mutation (SNP) | VAF 18/303 reads (6%) | called by muse, mutect2
- ERC1 | c.2590G>T p.E864* (on ENST00000360905 / NM_178040.4; = p.E836* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 131/254 reads (52%) | called by muse, mutect2, varscan2
- ERN1 | c.1033G>T p.G345* | Nonsense Mutation (SNP) | VAF 148/309 reads (48%) | called by muse, mutect2, varscan2
- ETS1 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 154/355 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXO1 | c.1840G>C p.G614R | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2
- EZR | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FAM181A | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 45/501 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- FGD5 | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 229/459 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF18 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 188/418 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- FNDC1 | c.2899G>T p.A967S | Missense Mutation (SNP) | VAF 223/449 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FSIP2 | c.17116G>T p.D5706Y | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- GHR | c.302G>T p.C101F | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLYCTK | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 237/484 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GNA15 | c.875C>A p.A292D | Missense Mutation (SNP) | VAF 138/296 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- GOLGA4 | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 175/332 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- GRIK2 | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 116/272 reads (43%) | called by muse, varscan2
- GRIP2 | c.2208G>T p.K736N (on ENST00000619221; = p.K639N on NM_001080423.4) | Missense Mutation (SNP) | VAF 101/229 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIP2 | c.994G>T p.A332S (on ENST00000619221; = p.A235S on NM_001080423.4) | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- GTPBP2 | c.1015C>A p.Q339K | Missense Mutation (SNP) | VAF 202/415 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- HABP4 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 150/305 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HGSNAT | c.1240G>T p.G414W | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIP1R | c.1912G>T p.A638S | Missense Mutation (SNP) | VAF 501/745 reads (67%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- HIVEP1 | c.2324C>A p.S775* | Nonsense Mutation (SNP) | VAF 178/380 reads (47%) | called by muse, mutect2, varscan2
- HIVEP1 | c.7589C>A p.S2530* | Nonsense Mutation (SNP) | VAF 183/419 reads (44%) | called by muse, mutect2, varscan2
- HLA-DMB | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 271/533 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HMGXB3 | c.1596G>T p.M532I (on ENST00000613459; = p.M286I on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/241 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IGKV1-16 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, varscan2
- IGSF22 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 199/388 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2
- IL16 | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 101/202 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSYN1 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 154/353 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- ITGA7 | c.3115G>T p.E1039* (on ENST00000555728; = p.E995* on NM_002206.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 146/293 reads (50%) | called by muse, mutect2, varscan2
- ITGB5 | c.2185G>T p.G729C | Missense Mutation (SNP) | VAF 164/332 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- JAK2 | c.1732G>A p.V578I | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCTD9 | c.1146_*14del | Nonstop Mutation (DEL) | VAF 39/131 reads (30%) | called by mutect2, pindel, varscan2
- KLHDC2 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 128/254 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by mutect2, varscan2
- KLHL34 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 242/401 reads (60%) | SIFT tolerated (0.43); PolyPhen benign (0.037); called by muse, varscan2
- KMT2C | c.10562C>G p.S3521* | Nonsense Mutation (SNP) | VAF 26/592 reads (4%) | called by muse, mutect2
- KRT77 | c.1405C>A p.L469M | Missense Mutation (SNP) | VAF 98/195 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC6 | c.779C>A p.S260* | Nonsense Mutation (SNP) | VAF 268/416 reads (64%) | called by muse, mutect2, varscan2
- LTBP4 | c.1880G>T p.C627F (on ENST00000308370 / NM_001042544.1; = p.C590F on NM_003573.2) | Missense Mutation (SNP) | VAF 170/302 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- LYZ | c.214_216del p.Y72del | In Frame Del (DEL) | VAF 148/293 reads (51%) | called by mutect2, pindel, varscan2
- MADD | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 176/348 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- MANEAL | c.394C>A p.H132N | Missense Mutation (SNP) | VAF 307/605 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MAP1LC3A | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 194/562 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP7D2 | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 191/276 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- MAPKBP1 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- MARCO | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 160/370 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MBLAC2 | c.399G>C p.W133C | Missense Mutation (SNP) | VAF 24/615 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- MBNL2 | c.670G>T p.G224W | Missense Mutation (SNP) | VAF 186/387 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MCCC1 | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 114/245 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED12L | c.3867G>T p.Q1289H | Missense Mutation (SNP) | VAF 127/264 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORC2 | c.89T>A p.F30Y | Missense Mutation (SNP) | VAF 100/222 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MPEG1 | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 149/387 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRPL2 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 187/368 reads (51%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- MTMR8 | c.1101+1G>A p.X367_splice | Splice Site (SNP) | VAF 29/144 reads (20%) | called by muse, mutect2, varscan2
- MUTYH | c.974_978del p.D325Gfs*202 | Frame Shift Del (DEL) | VAF 144/282 reads (51%) | called by mutect2, pindel, varscan2
- MYEF2 | c.1349C>A p.S450Y | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- MYH14 | c.3919G>T p.E1307* | Nonsense Mutation (SNP) | VAF 137/272 reads (50%) | called by muse, mutect2, varscan2
- MYO3A | c.306C>A p.L102= | Splice Region (SNP) | VAF 75/162 reads (46%) | called by muse, mutect2, varscan2
- MYO7B | c.3096G>T p.R1032S | Missense Mutation (SNP) | VAF 196/384 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NBPF11 | c.534G>T p.E178D | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- NDST1 | c.366G>T p.M122I | Missense Mutation (SNP) | VAF 228/429 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NETO1 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 120/256 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- NIN | c.5976G>T p.E1992D (on ENST00000382041 / NM_182946.1; = p.E1279D on NM_016350.4) | Missense Mutation (SNP) | VAF 187/350 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NME8 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 50/185 reads (27%) | called by muse, mutect2, varscan2
- NPC1L1 | c.1241C>A p.A414D | Missense Mutation (SNP) | VAF 202/626 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, varscan2
- NRK | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 114/186 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- OR2D3 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 22/415 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2
- OR51S1 | c.60C>A p.F20L | Missense Mutation (SNP) | VAF 138/302 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- OR5P2 | c.514C>A p.H172N | Missense Mutation (SNP) | VAF 156/304 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OTOP1 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 154/320 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OVGP1 | c.2015C>A p.S672Y | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- PATJ | c.5025G>T p.R1675S | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PCNX2 | c.1991G>T p.G664V | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- PDS5A | c.2362C>T p.P788S | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PDS5A | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEX1 | c.2814C>A p.F938L | Missense Mutation (SNP) | VAF 105/308 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PFKP | c.1749G>T p.M583I | Missense Mutation (SNP) | VAF 207/445 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHOX2B | c.761C>A p.A254E | Missense Mutation (SNP) | VAF 150/289 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3CG | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 189/405 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- PINK1 | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 300/591 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PITPNM1 | c.1380C>A p.F460L | Missense Mutation (SNP) | VAF 270/481 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PLEKHH3 | c.36C>A p.C12* | Nonsense Mutation (SNP) | VAF 217/415 reads (52%) | called by muse, mutect2, varscan2
- POLR2M | c.594G>T p.R198S | Missense Mutation (SNP) | VAF 169/365 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- POTEA | c.1662G>T p.K554N (on ENST00000519951 / NM_001005365.2; = p.K508N on NM_001002920.1) | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPFIA2 | c.1495C>A p.Q499K | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP1R3G | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 20/686 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- PRPF8 | c.1485G>T p.Q495H | Missense Mutation (SNP) | VAF 272/514 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR14L | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PRRC2A | c.6128C>A p.A2043D | Missense Mutation (SNP) | VAF 214/452 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRRT1B | c.486C>A p.F162L | Missense Mutation (SNP) | VAF 227/467 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- PUS10 | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 77/170 reads (45%) | called by muse, mutect2, varscan2
- RAPH1 | c.3203C>A p.P1068Q | Missense Mutation (SNP) | VAF 185/372 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIMBP3 | c.3337G>T p.D1113Y | Missense Mutation (SNP) | VAF 198/843 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- RIMS1 | c.3156G>T p.M1052I | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RNF213 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 205/421 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- RNF213 | c.2359C>A p.H787N | Missense Mutation (SNP) | VAF 159/315 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- RNFT1 | c.526G>T p.G176* | Nonsense Mutation (SNP) | VAF 103/205 reads (50%) | called by muse, mutect2, varscan2
- RP1 | c.2488C>A p.P830T | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- RUSC2 | c.2471C>A p.A824D | Missense Mutation (SNP) | VAF 256/516 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RYR1 | c.3053C>A p.P1018H | Missense Mutation (SNP) | VAF 294/572 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAP130 | c.2956G>A p.D986N | Missense Mutation (SNP) | VAF 112/259 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCARA5 | c.1481G>T p.R494I | Missense Mutation (SNP) | VAF 159/275 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN4A | c.2530C>A p.L844M | Missense Mutation (SNP) | VAF 191/373 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- SDK2 | c.5056A>T p.K1686* | Nonsense Mutation (SNP) | VAF 168/380 reads (44%) | called by muse, mutect2, varscan2
- SDK2 | c.4427T>A p.V1476E | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- SERPINB11 | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 165/363 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SFMBT2 | c.839C>A p.A280D | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SHISA7 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 280/576 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SKOR1 | c.2448G>C p.L816F | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.247); called by muse, mutect2
- SLC1A4 | c.1022C>A p.A341D | Missense Mutation (SNP) | VAF 111/206 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SMAD3 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 167/345 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SNAP91 | c.2067G>T p.Q689H | Missense Mutation (SNP) | VAF 132/325 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SORCS3 | c.2088C>A p.C696* | Nonsense Mutation (SNP) | VAF 99/233 reads (42%) | called by muse, mutect2, varscan2
- SP4 | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 73/375 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.857); called by mutect2, varscan2
- SPRY2 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 182/384 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPTBN4 | c.2697G>T p.E899D | Missense Mutation (SNP) | VAF 207/406 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- SRCAP | c.6125G>T p.C2042F | Missense Mutation (SNP) | VAF 95/182 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SSX2IP | c.1386G>T p.L462F | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- STX1A | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 50/528 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); called by muse, mutect2
- STYXL1 | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 125/360 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SYN2 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 127/242 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, varscan2
- TERB2 | c.524-1G>T p.X175_splice | Splice Site (SNP) | VAF 41/154 reads (27%) | called by muse, mutect2, varscan2
- THRB | c.754C>A p.Q252K | Missense Mutation (SNP) | VAF 121/237 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TMC2 | c.2428G>T p.A810S | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.075); called by muse, mutect2
- TMPRSS11B | c.362C>A p.P121Q | Missense Mutation (SNP) | VAF 139/265 reads (52%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- TMPRSS5 | c.394C>A p.L132I | Missense Mutation (SNP) | VAF 190/428 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- TOX3 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- TRERF1 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 173/353 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRERF1 | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 248/448 reads (55%) | called by muse, mutect2, varscan2
- TRIM32 | c.1419G>T p.W473C | Missense Mutation (SNP) | VAF 139/355 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TTN | c.33892G>T p.E11298* (on ENST00000591111; = p.E10371* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- TTPAL | c.189C>A p.D63E | Missense Mutation (SNP) | VAF 196/652 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.876); called by muse, varscan2
- TTYH2 | c.841del p.I281Sfs*2 | Frame Shift Del (DEL) | VAF 40/372 reads (11%) | called by mutect2, pindel, varscan2
- TUBB | c.838C>A p.Q280K | Missense Mutation (SNP) | VAF 322/633 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TUBD1 | c.1103C>A p.T368N | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TUT1 | c.2362C>A p.Q788K | Missense Mutation (SNP) | VAF 251/488 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- UBE4A | c.1910T>A p.I637N (on ENST00000252108 / NM_001204077.2; = p.I644N on NM_004788.4) | Missense Mutation (SNP) | VAF 140/280 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- USH2A | c.13988C>A p.P4663Q | Missense Mutation (SNP) | VAF 149/359 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.7472C>A p.A2491E | Missense Mutation (SNP) | VAF 104/207 reads (50%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- WAPL | c.1169C>A p.A390E | Missense Mutation (SNP) | VAF 127/273 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- WDFY4 | c.702C>A p.C234* | Nonsense Mutation (SNP) | VAF 151/299 reads (51%) | called by muse, mutect2, varscan2
- XKR4 | c.951G>T p.Q317H | Missense Mutation (SNP) | VAF 169/342 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XPR1 | c.373C>A p.H125N | Missense Mutation (SNP) | VAF 108/235 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YARS1 | c.55C>A p.Q19K | Missense Mutation (SNP) | VAF 126/370 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ZBTB5 | c.1421C>A p.A474E | Missense Mutation (SNP) | VAF 196/377 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZFP28 | c.1579C>A p.H527N | Missense Mutation (SNP) | VAF 120/265 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF461 | c.1262C>A p.A421D | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF518A | c.2288G>C p.R763T | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ZNF560 | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 178/357 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZNF585B | c.1784_1798del p.T595_H600delinsN | In Frame Del (DEL) | VAF 74/261 reads (28%) | called by mutect2, pindel, varscan2
- ZNF646 | c.3343C>A p.P1115T | Missense Mutation (SNP) | VAF 224/470 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by mutect2, varscan2
- ABCA12 | c.5988C>A p.G1996= (on ENST00000272895 / NM_173076.3; = p.G1678= on NM_015657.3) | Silent (SNP) | VAF 134/294 reads (46%) | catalogued as COSV55949497, COSV99792556; called by muse, mutect2, varscan2
- ABCA13 | c.13731C>A p.I4577= | Silent (SNP) | VAF 154/516 reads (30%) | called by muse, mutect2, varscan2
- ACSS3 | c.177C>A p.G59= | Silent (SNP) | VAF 78/443 reads (18%) | called by muse, mutect2, varscan2
- AHNAK2 | c.16575C>T p.I5525= | Silent (SNP) | VAF 23/332 reads (7%) | catalogued as rs1566894493; called by muse, mutect2
- AK4 | c.309C>A p.I103= | Silent (SNP) | VAF 96/209 reads (46%) | catalogued as rs763849329; called by muse, mutect2, varscan2
- AMELY | c.114T>G p.S38= | Silent (SNP) | VAF 23/155 reads (15%) | catalogued as COSV99293483; called by muse, mutect2, varscan2
- ARFGEF3 | c.6288C>A p.G2096= | Silent (SNP) | VAF 78/363 reads (21%) | catalogued as rs1177668471; called by muse, mutect2, varscan2
- ARL8A | c.366C>A p.G122= | Silent (SNP) | VAF 117/239 reads (49%) | called by muse, mutect2, varscan2
- ATP6V1B1 | c.390C>A p.G130= | Silent (SNP) | VAF 154/334 reads (46%) | called by muse, mutect2, varscan2
- AWAT2 | c.120G>T p.V40= | Silent (SNP) | VAF 173/278 reads (62%) | called by muse, mutect2, varscan2
- BPIFB3 | c.285G>T p.L95= | Silent (SNP) | VAF 121/401 reads (30%) | called by muse, mutect2, varscan2
- C1orf43 | c.543G>A p.E181= (on ENST00000368521 / NM_001297718.2; = p.E147= on NM_015449.4) | Silent (SNP) | VAF 71/230 reads (31%) | called by muse, mutect2, varscan2
- CACNA1D | c.1380C>A p.G460= | Silent (SNP) | VAF 89/222 reads (40%) | called by muse, mutect2, varscan2
- CACNA1F | c.5463C>A p.G1821= | Silent (SNP) | VAF 166/256 reads (65%) | called by muse, mutect2, varscan2
- CAPRIN2 | c.1851A>G p.K617= | Silent (SNP) | VAF 98/181 reads (54%) | catalogued as rs1414941365, COSV51834187; called by muse, mutect2, varscan2
- CBFA2T3 | c.807G>T p.L269= | Silent (SNP) | VAF 231/493 reads (47%) | called by muse, mutect2, varscan2
- CDK18 | c.690C>A p.A230= (on ENST00000506784 / NM_212503.3; = p.A200= on NM_002596.4) | Silent (SNP) | VAF 144/306 reads (47%) | called by muse, mutect2, varscan2
- CGN | c.2469G>T p.L823= | Silent (SNP) | VAF 66/622 reads (11%) | called by muse, mutect2, varscan2
- CHRM3 | c.213C>A p.I71= | Silent (SNP) | VAF 179/307 reads (58%) | catalogued as COSV99698113; called by muse, mutect2, varscan2
- CLCN4 | c.1011G>T p.L337= | Silent (SNP) | VAF 259/414 reads (63%) | called by muse, mutect2, varscan2
- CPNE1 | c.486G>T p.L162= (on ENST00000352393; = p.L167= on NM_003915.5) | Silent (SNP) | VAF 132/456 reads (29%) | called by muse, mutect2, varscan2
- CR1 | c.2346C>A p.L782= | Silent (SNP) | VAF 45/356 reads (13%) | called by muse, mutect2, varscan2
- CRB2 | c.1308C>A p.G436= | Silent (SNP) | VAF 34/544 reads (6%) | called by muse, mutect2
- DCP1A | c.1479G>A p.T493= | Silent (SNP) | VAF 143/296 reads (48%) | catalogued as rs782798835; called by muse, mutect2, varscan2
- DHX29 | c.3471A>G p.E1157= | Silent (SNP) | VAF 103/261 reads (39%) | called by muse, mutect2, varscan2
- DLEC1 | c.4542C>A p.I1514= | Silent (SNP) | VAF 153/296 reads (52%) | called by muse, mutect2, varscan2
- DSCAML1 | c.2703C>A p.T901= (on ENST00000321322; = p.T841= on NM_020693.4) | Silent (SNP) | VAF 160/342 reads (47%) | called by muse, mutect2, varscan2
- ENPP3 | c.2445G>T p.V815= | Silent (SNP) | VAF 98/229 reads (43%) | called by muse, mutect2, varscan2
- FAM171B | c.648C>A p.G216= | Silent (SNP) | VAF 90/178 reads (51%) | called by muse, mutect2, varscan2
- FASTK | c.1411C>A p.R471= | Silent (SNP) | VAF 176/598 reads (29%) | catalogued as COSV99879799; called by muse, mutect2, varscan2
- FBXL5 | c.1872G>T p.G624= | Silent (SNP) | VAF 121/230 reads (53%) | called by muse, mutect2, varscan2
- FGD6 | c.2817G>T p.L939= | Silent (SNP) | VAF 84/173 reads (49%) | called by muse, mutect2, varscan2
- GAB3 | c.12C>A p.G4= | Silent (SNP) | VAF 156/245 reads (64%) | called by muse, mutect2, varscan2
- GAPVD1 | c.90C>A p.L30= | Silent (SNP) | VAF 157/336 reads (47%) | called by muse, mutect2, varscan2
- GMEB2 | c.249G>T p.G83= | Silent (SNP) | VAF 18/542 reads (3%) | called by muse, mutect2
- GPR179 | c.1830C>A p.L610= (on ENST00000621958; = p.L609= on NM_001004334.4) | Silent (SNP) | VAF 163/334 reads (49%) | called by muse, mutect2, varscan2
- HAS3 | c.693C>T p.V231= | Silent (SNP) | VAF 36/315 reads (11%) | catalogued as rs752939821; called by muse, mutect2, varscan2
- HDLBP | c.900G>T p.V300= | Silent (SNP) | VAF 45/271 reads (17%) | called by muse, mutect2, varscan2
- HS3ST4 | c.375C>A p.G125= | Silent (SNP) | VAF 286/594 reads (48%) | called by muse, mutect2, varscan2
- KCNQ2 | c.2124C>A p.P708= (on ENST00000359125 / NM_172107.4; = p.P680= on NM_004518.6) | Silent (SNP) | VAF 34/1218 reads (3%) | called by muse, mutect2
- KCNQ3 | c.1272G>T p.L424= | Silent (SNP) | VAF 170/272 reads (63%) | catalogued as COSV66473200; called by muse, mutect2, varscan2
- LIX1 | c.727C>A p.R243= | Silent (SNP) | VAF 187/366 reads (51%) | catalogued as rs755613656, COSV99172825; called by muse, mutect2, varscan2
- MANBA | c.1891C>A p.R631= (on ENST00000642252; = p.R585= on NM_005908.4) | Silent (SNP) | VAF 142/267 reads (53%) | catalogued as COSV56966442; called by muse, mutect2, varscan2
- MTCL1 | c.4932C>A p.I1644= (on ENST00000306329 / NM_001378206.1; = p.I1325= on NM_015210.4) | Silent (SNP) | VAF 216/454 reads (48%) | called by muse, mutect2, varscan2
- MUC7 | c.819C>A p.S273= | Silent (SNP) | VAF 247/494 reads (50%) | catalogued as COSV59217631; called by mutect2, varscan2
- MVP | c.1587C>A p.I529= | Silent (SNP) | VAF 176/353 reads (50%) | called by muse, mutect2, varscan2
- NBAS | c.5604C>A p.G1868= | Silent (SNP) | VAF 169/337 reads (50%) | called by muse, mutect2, varscan2
- NELFB | c.456G>T p.V152= | Silent (SNP) | VAF 168/338 reads (50%) | called by muse, mutect2, varscan2
- OR6C74 | c.813G>T p.G271= | Silent (SNP) | VAF 136/299 reads (45%) | called by mutect2, varscan2
- PGAP3 | c.156C>A p.R52= | Silent (SNP) | VAF 191/337 reads (57%) | called by muse, mutect2, varscan2
- PPCS | c.342C>A p.G114= | Silent (SNP) | VAF 235/508 reads (46%) | called by muse, mutect2, varscan2
- PROSER3 | c.639C>A p.I213= | Silent (SNP) | VAF 245/518 reads (47%) | catalogued as rs370252048; called by muse, mutect2, varscan2
- PSD | c.915G>T p.L305= | Silent (SNP) | VAF 259/513 reads (50%) | called by muse, mutect2, varscan2
- PSD4 | c.1434C>A p.G478= | Silent (SNP) | VAF 202/411 reads (49%) | catalogued as COSV55526790; called by muse, mutect2, varscan2
- SALL3 | c.1740C>A p.T580= | Silent (SNP) | VAF 377/741 reads (51%) | called by muse, mutect2, varscan2
- SCN5A | c.4611G>T p.L1537= (on ENST00000333535 / NM_198056.3; = p.L1536= on NM_000335.5) | Silent (SNP) | VAF 170/372 reads (46%) | catalogued as COSV61118405; called by muse, mutect2, varscan2
- SLC38A7 | c.75G>T p.L25= | Silent (SNP) | VAF 230/437 reads (53%) | called by muse, mutect2, varscan2
- SRSF7 | c.339A>G p.G113= | Silent (SNP) | VAF 136/300 reads (45%) | called by muse, mutect2, varscan2
- ST18 | c.2058C>T p.D686= | Silent (SNP) | VAF 78/172 reads (45%) | called by muse, mutect2, varscan2
- SYT14 | c.123C>A p.L41= | Silent (SNP) | VAF 65/244 reads (27%) | catalogued as COSV55064894; called by muse, mutect2, varscan2
- SZRD1 | c.255C>A p.V85= | Silent (SNP) | VAF 255/518 reads (49%) | called by muse, mutect2, varscan2
- TCF7L1 | c.966C>A p.P322= | Silent (SNP) | VAF 160/338 reads (47%) | catalogued as COSV56399303, COSV56403502; called by muse, mutect2, varscan2
- TEX15 | c.5149C>A p.R1717= (on ENST00000256246; = p.R2100= on NM_001350162.2) | Silent (SNP) | VAF 104/221 reads (47%) | catalogued as COSV56341451; called by muse, mutect2, varscan2
- TTC5 | c.1071G>T p.L357= | Silent (SNP) | VAF 111/220 reads (50%) | called by muse, mutect2, varscan2
- UNC5D | c.1485G>T p.V495= | Silent (SNP) | VAF 45/383 reads (12%) | catalogued as COSV99777272; called by muse, mutect2, varscan2
- WDR97 | c.3870G>T p.V1290= | Silent (SNP) | VAF 46/382 reads (12%) | called by muse, mutect2, varscan2
- WWC3 | c.1470G>T p.G490= | Silent (SNP) | VAF 281/450 reads (62%) | called by muse, mutect2, varscan2
- ZFHX4 | c.1947T>C p.C649= | Silent (SNP) | VAF 139/272 reads (51%) | called by muse, mutect2, varscan2
- ZNF485 | c.600G>T p.T200= | Silent (SNP) | VAF 89/268 reads (33%) | called by muse, mutect2, varscan2
- ZNF490 | c.198C>T p.F66= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs548826072; called by muse, mutect2, varscan2
- ATP6AP1L | n.1805G>T | RNA (SNP) | VAF 182/404 reads (45%) | catalogued as COSV101205109; called by muse, mutect2, varscan2
- DIP2C | c.85+27438G>T | Intron (SNP) | VAF 22/450 reads (5%) | called by muse, mutect2
- GPN1 | c.111+221G>T | Intron (SNP) | VAF 133/270 reads (49%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+35143_1514+35150del | Intron (DEL) | VAF 94/240 reads (39%) | called by mutect2, pindel, varscan2
- NBPF25P | n.1418C>A | RNA (SNP) | VAF 37/321 reads (12%) | called by muse, mutect2, varscan2
- NRK | c.4354-870G>T | Intron (SNP) | VAF 118/182 reads (65%) | called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827959 G>T | 3'Flank (SNP) | VAF 114/212 reads (54%) | catalogued as COSV59428019; called by muse, mutect2, varscan2
- TNS1 | c.97-2445C>A | Intron (SNP) | VAF 138/304 reads (45%) | called by muse, mutect2, varscan2
- UBR4 | c.15009-53G>T | Intron (SNP) | VAF 204/429 reads (48%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.1855-651_1855-639del | Intron (DEL) | VAF 73/498 reads (15%) | called by mutect2, pindel, varscan2
